CPTAC case C3L-00413 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c4a660b0-7b34-4c80-98bb-0000e2b1c09a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1956; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 60.1 years (21,961 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 1,767 days (4.8 years); Progression or recurrence: no; Days to last follow up: 1,767 days (4.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.2 cm (a second GDC size field records 1.4 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 33; Margin status: Uninvolved.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 331 days; Disease response: Tumor Free.
- Days to follow up: 640 days (1.8 years); Disease response: Tumor Free.
- Days to follow up: 1,044 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,402 days (3.8 years); Disease response: Tumor Free.
- Days to follow up: 1,767 days (4.8 years); Disease response: Tumor Free.
- Days to follow up: 1,767 days (4.8 years); Disease response: Complete Response.

Other clinical attributes
- Weight: 108 kg; Height: 160 cm; BMI: 42.19.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Tobacco smoking quit year: 1996; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00413-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 234 mg; Time between excision and freezing: 13 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00413-21: Section location: anterior & posterior; Percent tumor nuclei: 95; Percent necrosis: 0.
- Sample C3L-00413-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 234 mg.
- Sample C3L-00413-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Time between excision and freezing: 13 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00413-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
